Somatic mutation profile of tumor specimen 0DG389 from CCDI case PBBRWR, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Alveolar rhabdomyosarcoma; Tissue or organ of origin: Lower limb, NOS; Age at diagnosis: 4.6 years (1,680 days).
Specimen 0DG389: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 690720c9-df31-4c5a-90eb-c56585906b37.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DG386 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be31b31a-dce6-442b-81a5-1ecfc1c16758

The open-access MAF lists 8 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, 3'UTR 2, Missense Mutation 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PSD3 | c.1657C>T p.R553W | Missense Mutation (SNP) | VAF 207/598 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.809); catalogued as rs377004772; called by muse, mutect2, varscan2
- DEDD2 | c.330G>A p.V110= | Splice Region (SNP) | VAF 20/161 reads (12%) | called by muse, mutect2, varscan2
- CFAP46 | c.6288G>T p.T2096= | Silent (SNP) | VAF 163/442 reads (37%) | called by muse, mutect2, varscan2
- FLG | c.11217C>T p.H3739= | Silent (SNP) | VAF 68/445 reads (15%) | catalogued as rs774213318, COSV64244306; called by muse, mutect2, varscan2
- PLIN4 | c.372G>A p.V124= (on ENST00000301286; = p.V139= on NM_001367868.2) | Silent (SNP) | VAF 22/208 reads (11%) | catalogued as rs754793086; called by muse, varscan2
- TMEM41B | c.832C>T p.L278= | Silent (SNP) | VAF 304/845 reads (36%) | catalogued as COSV55157039; called by muse, mutect2, varscan2
- ADCK1 | c.*526C>A | 3'UTR (SNP) | VAF 92/212 reads (43%) | called by muse, mutect2, varscan2
- TRIM8 | c.*824G>T | 3'UTR (SNP) | VAF 176/429 reads (41%) | catalogued as rs371789796, COSV100193540; called by muse, mutect2, varscan2
